Somatic mutation profile of tumor specimen C3L-03268-01 (aliquot CPT0249450006) from CPTAC case C3L-03268, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 78.5 years (28,668 days).
Specimen C3L-03268-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a89979e4-82c6-45c5-b6bf-d430fc2a4bc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03268-32 (Blood Derived Normal), aliquot CPT0240420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4a7dba2-40e7-4e62-8a0f-3d63eadfa975

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Nonsense Mutation 5, Frame Shift Del 1, Intron 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 48/284 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCY3 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.835); catalogued as COSV99568963; called by muse, mutect2, varscan2
- AIFM1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as CM157342; called by muse, mutect2, varscan2
- ARFIP1 | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1323363245; called by muse, mutect2, varscan2
- CYP2B6 | c.905C>A p.T302N | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1261998210; called by muse, mutect2, varscan2
- DSP | c.6709G>T p.E2237* | Nonsense Mutation (SNP) | VAF 32/273 reads (12%) | catalogued as COSV101131174; called by muse, mutect2, varscan2
- FHDC1 | c.1678G>T p.G560C | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV52602035; called by muse, mutect2
- GCGR | c.163+3G>A | Splice Region (SNP) | VAF 9/97 reads (9%) | catalogued as rs868520740; called by muse, mutect2
- NKX2-1 | c.536G>C p.R179P | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM142000, COSV61389649; called by muse, mutect2, varscan2
- P4HTM | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV59086225; called by muse, mutect2
- PES1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs753455922; called by muse, mutect2, varscan2
- RGR | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 62/665 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as rs374080340; called by muse, mutect2
- SH2B2 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99074760; called by muse, mutect2
- SHOX | c.582C>A p.C194* | Nonsense Mutation (SNP) | VAF 36/476 reads (8%) | catalogued as CM074529; called by muse, mutect2
- SOX9 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 19/221 reads (9%) | catalogued as COSV55422188; called by muse, mutect2
- VPS4A | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs755129371; called by muse, mutect2, varscan2
- ASTN2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.3726G>T p.K1242N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2
- CSPP1 | c.2140A>T p.R714* (on ENST00000676605; = p.R673* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- DNAH17 | c.6185A>G p.D2062G | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EHMT1 | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- EYS | c.6314A>T p.Q2105L | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- FHDC1 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 25/366 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2
- GCG | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GCG | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); called by mutect2, varscan2
- GZMA | c.556A>G p.N186D | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- HSPA12A | c.1646A>G p.K549R | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- IL1RAPL1 | c.1759G>C p.V587L | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- LAMA4 | c.4757G>A p.W1586* (on ENST00000230538 / NM_001105206.3; = p.W1579* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/327 reads (8%) | called by muse, mutect2
- LINS1 | c.1974G>T p.K658N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.498); called by muse, mutect2
- MAST1 | c.4169G>A p.R1390Q | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PTBP2 | c.523A>G p.T175A (on ENST00000426398 / NM_001300986.2; = p.T167A on NM_021190.4) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7B | c.1982T>A p.M661K | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TPP1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2
- TSC22D1 | c.2735A>T p.D912V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- UBE3B | c.2830G>T p.G944C | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USH2A | c.2238del p.C747Afs*9 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel, varscan2
- VCAN | c.7234A>G p.K2412E | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- WDR26 | c.2177C>T p.P726L (on ENST00000414423 / NM_001379403.1; = p.P626L on NM_025160.7) | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); called by muse, mutect2
- ZNF630 | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ABCA12 | c.4203C>G p.T1401= (on ENST00000272895 / NM_173076.3; = p.T1083= on NM_015657.3) | Silent (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2, varscan2
- CLCN4 | c.60G>A p.P20= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs944846878; called by muse, mutect2
- FAM189A1 | c.726C>G p.P242= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2
- KIT | c.2850G>T p.V950= | Silent (SNP) | VAF 34/379 reads (9%) | called by muse, mutect2
- LRRTM1 | c.1524C>A p.G508= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- NGDN | c.615C>T p.V205= | Silent (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- NSD1 | c.2946G>T p.G982= | Silent (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- PTDSS1 | c.1233C>T p.H411= | Silent (SNP) | VAF 20/221 reads (9%) | catalogued as COSV61266085; called by muse, mutect2
- SAMD11 | c.1656G>A p.V552= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs1198509075; called by muse, mutect2
- AL353804.7 | chrX:73849812 G>C | 5'Flank (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- STOML3 | c.53-3305T>A | Intron (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2, varscan2
